FM case AD6400 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/0d3fa0ad-1f68-4985-ab73-4d61f6b3f4ac

Male, 78.5 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
